Surgical pathology report (de-identified scan), TCGA case TCGA-BG-A3PP, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BG-A3PP-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: UTERUS WITH BILATERAL ADNEXA, TOTAL ABDOMINAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY -
A. SEROUS ADENOCARCINOMA OF ENDOMETRIUM INVOLVING 80% OF ENDOMETRIAL SURFACE AND INVADING APPROXIMATELY 85% OF MYOMETRIUM (GRADE 3, STAGE 2).
B. MULTIFOCAL LYMPHOVASCULAR INVASION IDENTIFIED.
C. ADENOCARCINOMA INVADERS ENDOCERVICAL GLANDS AND CERVICAL STROMA.
D. BILATERAL OVARIES NEGATIVE FOR TUMOR, WITH PHYSIOLOGIC CHANGES AND EPITHELIAL INCLUSIONS.
E. BILATERAL FALLOPIAN TUBES, UNREMARKABLE.

PART 2: LYMPH NODES, LEFT PELVIC, DISSECTION -
TWO LYMPH NODES, NEGATIVE FOR TUMOR (0/2).

PART 3: LYMPH NODES, LEFT PERIAORTIC, DISSECTION -
A. NEGATIVE FOR TUMOR.
B. NO LYMPH NODE TISSUE IDENTIFIED.

PART 4: LYMPH NODES, RIGHT PELVIC, DISSECTION -
A. NEGATIVE FOR TUMOR.
B. NO LYMPH NODE TISSUE IDENTIFIED.

PART 5: LYMPH NODES, RIGHT PERIAORTIC, DISSECTION -
A. ONE LYMPH NODE. NEGATIVE FOR TUMOR (0/1).
B. FOCAL LYMPHOVASCULAR INVASION IN PERILYMPHATIC VESSEL.

PART 6: OMENTUM, OMENTECTOMY -
A. NEGATIVE FOR TUMOR.
B. FOCAL MESOTHELIAL PROLIFERATION.

100-0-3

adenocarcinoma, serous, NOS 8441/3

Site: endometrium c54.1

2/15/12
lw

Addendum

Pelvic cytology is suspicious for malignant cells.

CASE SYNOPSIS:

SYNOPTIC - PRIMARY UTERINE ENDOMETRIAL CARCINOMA & CARCINOSARCOMA : HYSTERECTOMY

TUMOR TYPE:	SERIOUS ADENOCARCINOMA
HISTOLOGIC GRADE (epithelial neoplasm) [combined architectural and nuclear]:	Poorly differentiated (FIGO 3)
ARCHITECTURAL GRADE:	Poorly differentiated
NUCLEAR GRADE:	Grade 3
TUMOR SIZE:	Maximum dimension: 43 mm
PERCENT OF ENDOMETRIAL SURFACE INVOLVEMENT:	Anterior endometrium: 80 %, Posterior endometrium: 80 %
DEPTH OF INVASION:	Greater than or equal to 1/2 thickness of myometrium
STRUCTURES INVOLVED:	Endocervical glands, Cervical stroma
ANGIOLYMPHATIC INVASION:	Yes
LYMPH NODES POSITIVE:	Number of lymph nodes positive: 0
LYMPH NODES EXAMINED:	Total number of lymph nodes examined: 3
T STAGE, PATHOLOGIC:	pT2
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	Not applicable
FIGO STAGE:	II

Recurrence/Synchronous Primary Tumor		

Source: NCI Genomic Data Commons file c1ce7715-08ef-4c31-8fdb-1a3204fb4fed (TCGA-BG-A3PP.728D12CF-B846-49B7-8B16-463460CAD5C0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).